CCDI case PBCNFN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/456c8fc7-7acc-46fe-807d-3425be13bc66

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 8.6 years (3,123 days).

Biospecimens (3 samples)
- Sample 0DVXF6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVXF9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVXFQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
